Somatic mutation profile of tumor specimen 0DVCF7 from CCDI case PBCMLK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 13.6 years (4,960 days).
Specimen 0DVCF7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 839f8adc-e67c-43a4-960c-6b8551b33207.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVCFW (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/43e781bf-4078-4412-81ec-cf026b969642

The open-access MAF lists 33 somatic variants for this specimen: 24 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 7, Frame Shift Ins 2, 3'UTR 1, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1258T>C p.C420R | Missense Mutation (SNP) | VAF 342/752 reads (45%) | hotspot (GDC flag); SIFT tolerated (0.21); PolyPhen possibly damaging (0.908); catalogued as rs121913272, COSV55874020; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RB1 | c.2107-1G>C p.X703_splice | Splice Site (SNP) | VAF 161/187 reads (86%) | catalogued as rs587778860, CS125752, COSV57297199, COSV57304025; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.470T>G p.V157G | Missense Mutation (SNP) | VAF 582/667 reads (87%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM138009, CM161671, COSV52675572, COSV52699845, COSV52722122; called by muse, mutect2, varscan2
- ASH1L | c.2951G>A p.R984H | Missense Mutation (SNP) | VAF 238/549 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.747); catalogued as rs1187547460, COSV64207177; called by muse, mutect2, varscan2
- CD1E | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 424/917 reads (46%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs868718790, COSV63769843; called by muse, mutect2, varscan2
- GBA3 | c.1382G>A p.R461Q | Missense Mutation (SNP) | VAF 175/688 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs748201442, COSV72437852; called by muse, mutect2, varscan2
- KCNK4 | c.901C>G p.Q301E | Missense Mutation (SNP) | VAF 233/432 reads (54%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs747339416; called by muse, mutect2, varscan2
- LRRK2 | c.2753G>A p.R918Q | Missense Mutation (SNP) | VAF 342/769 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs959668316; called by muse, mutect2, varscan2
- OBSCN | c.10384G>A p.V3462M | Missense Mutation (SNP) | VAF 513/986 reads (52%) | SIFT tolerated (0.46); PolyPhen benign (0.051); catalogued as rs374638490; called by muse, mutect2, varscan2
- OR1L1 | c.985G>A p.V329I (on ENST00000373686; = p.V279I on NM_001005236.3) | Missense Mutation (SNP) | VAF 263/656 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.05); catalogued as rs555833314, COSV58936609; called by muse, mutect2, varscan2
- OR5T3 | c.868T>C p.Y290H | Missense Mutation (SNP) | VAF 275/752 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV57382269; called by muse, varscan2
- ADCY5 | c.3077A>C p.K1026T | Missense Mutation (SNP) | VAF 257/638 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- ARHGAP36 | c.575G>T p.S192I | Missense Mutation (SNP) | VAF 354/1120 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 40/1410 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- CFAP47 | c.7681G>T p.A2561S | Missense Mutation (SNP) | VAF 134/1042 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.022); called by muse, varscan2
- COL6A2 | c.2662C>G p.Q888E | Missense Mutation (SNP) | VAF 70/848 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.757); called by muse, mutect2
- FRYL | c.8053_8056dup p.A2686Gfs*13 | Frame Shift Ins (INS) | VAF 198/964 reads (21%) | called by mutect2, varscan2
- KCNA1 | c.1247A>C p.H416P | Missense Mutation (SNP) | VAF 330/775 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- RNF128 | c.46G>A p.G16S | Missense Mutation (SNP) | VAF 469/1288 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- SERTAD4 | c.72dup p.Y25Vfs*8 | Frame Shift Ins (INS) | VAF 176/974 reads (18%) | called by mutect2, varscan2
- SRF | c.435G>C p.K145N | Missense Mutation (SNP) | VAF 345/614 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TBC1D30 | c.2070G>T p.M690I (on ENST00000542120; = p.M527I on NM_015279.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 74/1562 reads (5%) | SIFT tolerated (0.63); PolyPhen benign (0.007); called by muse, mutect2
- TCEA3 | c.750C>A p.N250K | Missense Mutation (SNP) | VAF 213/1180 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- ZNF578 | c.1620A>T p.K540N | Missense Mutation (SNP) | VAF 26/699 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- ALOX12B | c.294C>T p.H98= | Silent (SNP) | VAF 65/398 reads (16%) | called by muse, mutect2, varscan2
- HDHD5 | c.148C>T p.L50= (on ENST00000336737 / NM_033070.3; = p.L20= on NM_017829.5) | Silent (SNP) | VAF 187/696 reads (27%) | called by muse, mutect2, varscan2
- KCNN4 | c.519C>A p.V173= | Silent (SNP) | VAF 279/694 reads (40%) | catalogued as rs139516899; called by muse, mutect2, varscan2
- OGT | c.1971T>A p.P657= | Silent (SNP) | VAF 241/777 reads (31%) | called by muse, mutect2, varscan2
- SLCO1B1 | c.657T>A p.G219= | Silent (SNP) | VAF 40/1153 reads (3%) | called by muse, mutect2
- TTLL4 | c.1221G>A p.L407= | Silent (SNP) | VAF 325/729 reads (45%) | called by muse, mutect2, varscan2
- ZNF536 | c.687C>T p.H229= | Silent (SNP) | VAF 166/322 reads (52%) | catalogued as rs1359313801; called by muse, mutect2, varscan2
- NDUFAF3 | c.*79T>C | 3'UTR (SNP) | VAF 51/108 reads (47%) | catalogued as rs567619323; called by muse, varscan2
- P2RY6 | c.-266T>C | 5'UTR (SNP) | VAF 30/666 reads (5%) | called by muse, mutect2
